Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A6X5, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A6X5-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: F

Age:

Date of surgery:

Localization: L frontal

Diagnosis: Oligoastrocytoma (grade II WHO)

Name of Pathologist:

ICD-O-3

Oligoastrocytoma, grade II
9382/3 NGS
Site Brain, supratentorial
C71.0

JW 8/12/13

Source: NCI Genomic Data Commons file 53dd6a4a-7e53-4783-9dbd-53ec5d35c91b (TCGA-QH-A6X5.5125411F-F380-4367-8A21-9284B5779B9D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).